HCMI case HCM-BROD-0413-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bea1726c-ae87-4697-8d35-06c37eee0999

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1964; Vital status: Dead; Days to death: 508 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.7; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 53.1 years (19,390 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 23 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine + Nab-paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 370 days (1.0 years); Days to treatment end: 436 days (1.2 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 310 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 310 days.
- Follow-up contacts recording only the day: day 506, day 508.

Molecular and laboratory tests
- CDKN2A mutation, nos: Negative.
- GNAS mutation, nos: Negative.
- KRAS mutation, nos: Negative.
- RNF43 mutation, nos: Negative.
- TP53 mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 182 cm; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-BROD-0413-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Samples HCM-BROD-0413-C25-85N, HCM-BROD-0413-C25-85O (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
